Somatic mutation profile of tumor specimen 0DU3LN from CCDI case PBCJRP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.4 years (3,797 days).
Specimen 0DU3LN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af616d3b-4f33-49a0-9e4c-47dcb5f71022.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU3MG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/754fccfa-792c-4e79-9727-fa0381a8584b

The open-access MAF lists 42 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Intron 6, 5'UTR 2, Splice Region 1, 5'Flank 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMPK | c.220C>A p.L74M | Missense Mutation (SNP) | VAF 78/864 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568585550, COSV52176483; called by muse, mutect2
- KIAA1614 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 545/1243 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs1051676676; called by muse, mutect2, varscan2
- LPAR3 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 515/1246 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65455466; called by muse, mutect2, varscan2
- PLA1A | c.1004C>G p.P335R | Missense Mutation (SNP) | VAF 171/925 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99846111; called by muse, mutect2, varscan2
- PSG3 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 101/1364 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs368279604; called by muse, mutect2
- SI | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 477/1169 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as rs530009542, COSV52278560; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM48 | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 162/1175 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs777138836; called by muse, mutect2, varscan2
- ADAMTSL2 | c.233G>T p.R78M | Missense Mutation (SNP) | VAF 86/1282 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CAMP | c.346A>G p.T116A (on ENST00000296435; = p.T113A on NM_004345.5) | Missense Mutation (SNP) | VAF 80/1176 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.053); called by muse, mutect2
- EFEMP2 | c.429G>T p.L143F | Missense Mutation (SNP) | VAF 118/912 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- FCHO2 | c.797-3C>A | Splice Region (SNP) | VAF 343/773 reads (44%) | called by muse, mutect2, varscan2
- FMO4 | c.1508C>G p.P503R | Missense Mutation (SNP) | VAF 159/898 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LPCAT3 | c.1260C>G p.Y420* | Nonsense Mutation (SNP) | VAF 665/1560 reads (43%) | called by muse, mutect2, varscan2
- MN1 | c.1970G>T p.G657V | Missense Mutation (SNP) | VAF 60/1148 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.858); called by muse, mutect2
- PLEKHG5 | c.478G>C p.D160H (on ENST00000400915 / NM_001042663.3; = p.D123H on NM_020631.6) | Missense Mutation (SNP) | VAF 453/1101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRJ | c.1970A>G p.Y657C | Missense Mutation (SNP) | VAF 67/1402 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RTL1 | c.46A>G p.K16E | Missense Mutation (SNP) | VAF 144/1762 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.27); called by muse, mutect2
- SEMA3A | c.1046G>A p.R349K | Missense Mutation (SNP) | VAF 286/1391 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SPACA3 | c.602G>C p.C201S | Missense Mutation (SNP) | VAF 145/1086 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPC25 | c.465G>T p.Q155H | Missense Mutation (SNP) | VAF 40/587 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TEX11 | c.1217G>A p.R406K (on ENST00000344304; = p.R391K on NM_031276.3) | Missense Mutation (SNP) | VAF 231/1230 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- UCK1 | c.30G>C p.E10D | Missense Mutation (SNP) | VAF 55/471 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZRSR2 | c.11C>A p.P4H | Missense Mutation (SNP) | VAF 173/1017 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ACHE | c.1191G>C p.G397= | Silent (SNP) | VAF 68/683 reads (10%) | called by muse, mutect2, varscan2
- CD5 | c.1257C>A p.G419= | Silent (SNP) | VAF 147/757 reads (19%) | called by muse, mutect2, varscan2
- CPS1 | c.597T>C p.N199= | Silent (SNP) | VAF 193/1007 reads (19%) | called by muse, mutect2, varscan2
- DYNC2I2 | c.393G>A p.A131= | Silent (SNP) | VAF 334/823 reads (41%) | catalogued as rs760786107; called by muse, mutect2, varscan2
- KCNV2 | c.765C>G p.S255= | Silent (SNP) | VAF 403/994 reads (41%) | called by muse, mutect2, varscan2
- MATN4 | c.1732C>A p.R578= (on ENST00000372754; = p.R537= on NM_003833.4) | Silent (SNP) | VAF 244/1216 reads (20%) | called by muse, mutect2, varscan2
- OR10X1 | c.129T>C p.L43= | Silent (SNP) | VAF 279/1083 reads (26%) | called by muse, mutect2, varscan2
- SALL3 | c.2973G>A p.A991= | Silent (SNP) | VAF 159/745 reads (21%) | catalogued as rs372071983; called by muse, mutect2, varscan2
- TBX2 | c.1497C>A p.G499= | Silent (SNP) | VAF 331/1133 reads (29%) | called by muse, mutect2, varscan2
- ALKBH7 | c.-5G>A | 5'UTR (SNP) | VAF 84/876 reads (10%) | called by muse, mutect2, varscan2
- C3 | c.2584-18C>T | Intron (SNP) | VAF 187/866 reads (22%) | called by muse, mutect2, varscan2
- FUNDC2 | c.*93C>T | 3'UTR (SNP) | VAF 29/105 reads (28%) | called by muse, mutect2, varscan2
- IL2RG | c.115+13G>T | Intron (SNP) | VAF 120/735 reads (16%) | catalogued as rs751152396; called by muse, mutect2, varscan2
- MFSD10 | c.915-63C>T | Intron (SNP) | VAF 154/677 reads (23%) | catalogued as rs1184746074; called by muse, mutect2, varscan2
- OLFML3 | c.115-108C>T | Intron (SNP) | VAF 23/306 reads (8%) | called by muse, mutect2
- SIN3B | c.1363-47G>T | Intron (SNP) | VAF 159/747 reads (21%) | called by muse, mutect2, varscan2
- TOP3B | c.1654+18G>A | Intron (SNP) | VAF 118/502 reads (24%) | called by muse, mutect2, varscan2
- UBQLN4 | c.-92T>C | 5'UTR (SNP) | VAF 27/157 reads (17%) | called by muse, mutect2, varscan2
- WNK2 | chr9:93184924 A>T | 5'Flank (SNP) | VAF 131/680 reads (19%) | called by mutect2, varscan2
